TARGET case TARGET-30-PARVMU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4c98e90e-1179-5282-816f-3edb03f3284e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Dead; Days to death: 2,285 days (6.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C72.9; Tissue or organ of origin: Nervous system, NOS; Classification of tumor: primary; Age at diagnosis: 0.3 years (123 days); Year of diagnosis: 2008; Days to last follow up: 2,285 days (6.3 years); Cog neuroblastoma risk group: Intermediate Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 3; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 80.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 958 days (2.6 years); Days to first event: 958 days (2.6 years); First event: Progression.
- Days to follow up: 2,285 days (6.3 years); Year of follow up: 2014.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARVMU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PARVMU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2285
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.13
- Histology: Favorable
- MKI: Low
- ICDO Description: Nervous system, NOS Epidural Central nervous system
- Site of Relapse: Primary site
